Gene-level copy-number profile of tumor specimen HCM-WCMC-1340-C54-01A from HCMI case HCM-WCMC-1340-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage I; FIGO stage: Stage IIIA; Age at diagnosis: 64.0 years (23,370 days).
Specimen HCM-WCMC-1340-C54-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83bcb037-9cfc-4661-b7cc-904293f62e7f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1340-C54-12A (saliva); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/7cc14b6d-ed11-410c-81dc-897e735cd214

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 4,033; copy number 2: 53,756; copy number 3: 408; copy number 4: 111; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,617,160–91,723,605, 5 genes (within-gene range 0–2): LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr2:130,742,959–130,768,134, 2 genes: AC140481.1, AMER3.
- chr7:76,521,611–76,532,692, 3 genes: AC004980.4, Y_RNA, AC004980.3.
- chr9:123,402,525–123,485,622, 2 genes (within-gene range 0–2): MIR601, MIR7150.
- chr9:138,129,399–138,253,217, 6 genes: AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr11:70,398,404–71,423,423, 12 genes (within-gene range 0–2): CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P.
- chr16:46,469,341–46,790,407, 13 genes (within-gene range 0–2): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr16:89,575,758–90,222,851, 34 genes: CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:45,034–94,330, 5 genes: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2.
- chr20:31,563,166–31,581,214, 4 genes (within-gene range 0–1): HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr20:32,443,059–32,585,074, 4 genes (within-gene range 0–2): NOL4L, AL034550.1, AL034550.3, AL034550.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,536,861–105,549,694, 2 genes, copy number 5: ATP5MC1P1, ELK2BP.

Autosomal genes at a single copy (total copy number 1): 2,105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
